Somatic mutation profile of tumor specimen PCProject_0087_T1_WES (aliquot PCProject_0087_T1_WES_1) from CMI case PCProject_0087, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.4 years (18,789 days).
Specimen PCProject_0087_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d487fb7-4023-484f-a0bd-2e59aecef891.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0087_BLOOD_BC (Blood Derived Normal), aliquot PCProject_0087_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8167f94-321d-42bf-ae30-f0b6747b7c3b

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 3, Frame Shift Ins 1, 3'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GGT5 | c.1114C>A p.Q372K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs1299368103; called by muse, mutect2
- GNB1L | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201666394; called by muse, mutect2, varscan2
- ISM1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs1311305351; called by muse, mutect2, varscan2
- PRRX1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1270473736, CM143963, COSV53413010; called by muse, mutect2
- CEP131 | c.2112G>T p.K704N (on ENST00000269392 / NM_001319228.2; = p.K701N on NM_014984.4) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CROCC | c.2605C>G p.R869G | Missense Mutation (SNP) | VAF 25/301 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- DIRAS3 | c.319dup p.A107Gfs*26 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by mutect2, pindel, varscan2
- ERICH1 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, varscan2
- HNRNPM | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MGA | c.3177_3178del p.L1061Sfs*30 | Frame Shift Del (DEL) | VAF 10/122 reads (8%) | called by mutect2, pindel
- YTHDF2 | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4G3 | c.264G>A p.P88= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2
- GRIK3 | c.927G>C p.R309= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as rs1179279755, COSV66136673; called by muse, mutect2
- KLC4 | c.894C>G p.L298= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1227730352; called by muse, varscan2
- PIEZO1 | c.402C>G p.V134= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1197725004, COSV104422602; called by mutect2, varscan2
- FAM161A | c.*618A>G | 3'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as rs980814053; called by muse, varscan2
- LINC01559 | n.435A>G | RNA (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- QRICH2 | c.207+2942G>A | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- QRICH2 | c.207+2941T>C | Intron (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
